Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7X2, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7X2-01A (Primary Tumor).

Gross:

Left adrenal gland with ovoid tumor (dimension 90x60x45 mm, weight 72 g), tumor with fibrous capsule 60x50x45 mm.

On cut, adrenal cortex with ochre yellow color, 2 mm thick, tumor with grey-pink color and soft consistency, with central hemorrhage.

Representative excision with largest tumor diameter was processed in four blocks.

Micro:

Diffusely alveolarly growing pheochromocytoma with fibrous capsule with signs of fresh and old hemorrhage and scarification. On periphery, remnants of regular adrenal cortex were found.

Imunohistochemic examination:

S100 protein – no positive sustentacular cells were found, internal control in the excision (small nerves in the periadrenal tissue) positive

KI 67 – 1-2% tumor nuclei positive

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 4

Procurement date:

Confirmation date:

CCCF ICD-O-3
Pheochromocytoma, NOS 8760/0
path
Pheochromocytoma, malignant 8760/3
Site: (2) Adrenal Gland NOS 874.9
QW 10/10/13

Source: NCI Genomic Data Commons file 761f8c87-40b6-43ac-8b43-314b81f12571 (TCGA-S7-A7X2.B0B9A46D-0D6F-46AA-A603-91CB569177A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).